MMRF case MMRF_1931 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1ebbf486-4cfa-44e1-a1a6-87ac0f09f0ce

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Age at index: 72 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 72.6 years (26,526 days); ISS stage: III; Days to last known disease status: 1,062 days (2.9 years); Days to last follow up: 1,062 days (2.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 310 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 796 days (2.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 3): M Protein 6.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.189 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.737 mg/dL; Immunoglobulin G 2.35 g/L; Immunoglobulin A 69.8 g/L; Immunoglobulin M 0.156 g/L; Beta 2 Microglobulin 7 µg/mL; Lactate Dehydrogenase 1.1 µkat/L; Hemoglobin 5.15 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 6.32 mmol/L; Calcium 2.25 mmol/L; Albumin 25.8 g/L; Total Protein 9.65 g/dL; Glucose 4.62 mmol/L.
- Day 99 (ECOG 3): Serum Free Immunoglobulin Light Chain, Kappa 0.135 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.09 mg/dL; Immunoglobulin G 7.31 g/L; Immunoglobulin A 6.16 g/L; Immunoglobulin M 0.349 g/L; Beta 2 Microglobulin 2.57 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 10.7 ×10⁹/L; Absolute Neutrophil 7.7 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 5.64 mmol/L; Calcium 2.37 mmol/L; Albumin 38.8 g/L; Total Protein 7.38 g/dL; Glucose 5.45 mmol/L.
- Day 183 (ECOG 2): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.727 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.315 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 5.32 g/L; Immunoglobulin M 0.567 g/L; Beta 2 Microglobulin 2.17 µg/mL; Hemoglobin 8.99 mmol/L; Leukocytes 10.7 ×10⁹/L; Absolute Neutrophil 7.2 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.46 mmol/L; Calcium 2.46 mmol/L; Albumin 38.2 g/L; Total Protein 7.4 g/dL; Glucose 6.93 mmol/L.
- Day 254 (ECOG 2): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.579 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 9.49 g/L; Immunoglobulin A 3.67 g/L; Immunoglobulin M 0.414 g/L; Beta 2 Microglobulin 1.88 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 53.9 µmol/L; Calcium 2.39 mmol/L; Albumin 35 g/L; Total Protein 7.11 g/dL; Glucose 13.8 mmol/L.
- Day 361 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.268 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.332 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 3.86 g/L; Immunoglobulin M 0.552 g/L; Beta 2 Microglobulin 2.19 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 6.8 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 3.82 mmol/L; Calcium 2.57 mmol/L; Albumin 37.3 g/L; Total Protein 7.57 g/dL; Glucose 11.6 mmol/L.
- Day 425: M Protein 0.00067 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 257 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 241 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 6.67 g/L; Immunoglobulin M 0.546 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 207 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 39.3 g/L; Total Protein 7.86 g/dL.
- Day 520: M Protein 1.59 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.166 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 7.53 g/L; Immunoglobulin A 15.3 g/L; Immunoglobulin M 0.391 g/L; Beta 2 Microglobulin 2.98 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 11.4 ×10⁹/L; Absolute Neutrophil 7.7 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 51.3 µmol/L; Calcium 2.53 mmol/L; Albumin 36.5 g/L; Total Protein 7.73 g/dL; Glucose 7.65 mmol/L.
- Day 621 (ECOG 1): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.215 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.881 mg/dL; Immunoglobulin G 5.61 g/L; Immunoglobulin A 29.8 g/L; Immunoglobulin M 0.237 g/L; Beta 2 Microglobulin 3.08 µg/mL; Hemoglobin 7.44 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 55.7 µmol/L; Calcium 2.26 mmol/L; Albumin 34.1 g/L; Total Protein 8.28 g/dL; Glucose 7.1 mmol/L.
- Day 733 (ECOG 0): M Protein 3.15 g/dL; Immunoglobulin G 4.13 g/L; Immunoglobulin A 38.3 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 4.5 µg/mL; Hemoglobin 6.26 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 4.33 mmol/L; Calcium 2.33 mmol/L; Albumin 31 g/L; Total Protein 8.88 g/dL; Glucose 7.48 mmol/L.
- Day 796 (ECOG 2): M Protein 4.24 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.729 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 3.73 g/L; Immunoglobulin A 47.3 g/L; Immunoglobulin M 0.158 g/L; Beta 2 Microglobulin 5.2 µg/mL; Hemoglobin 5.77 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5.5 mmol/L; Calcium 2.22 mmol/L; Albumin 30 g/L; Total Protein 9.25 g/dL; Glucose 7.92 mmol/L.
- Day 901 (ECOG 1): M Protein 1.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 6.77 g/L; Immunoglobulin A 14 g/L; Immunoglobulin M 0.499 g/L; Beta 2 Microglobulin 2.65 µg/mL; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 10.6 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 3.67 mmol/L; Calcium 2.26 mmol/L; Albumin 34.4 g/L; Total Protein 7.19 g/dL; Glucose 5.45 mmol/L.
- Day 992 (ECOG 1): M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.54 mg/dL; Immunoglobulin G 7.17 g/L; Immunoglobulin A 1.64 g/L; Immunoglobulin M 0.725 g/L; Beta 2 Microglobulin 2.01 µg/mL; Lactate Dehydrogenase 3.48 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 4 mmol/L.
- Day 1,062: M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.75 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 2.29 g/L; Immunoglobulin M 0.796 g/L; Beta 2 Microglobulin 2.64 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 4.83 mmol/L; Calcium 2.22 mmol/L; Albumin 35.7 g/L; Total Protein 7.03 g/dL; Glucose 8.69 mmol/L.

Other clinical attributes
- Day -5: Weight: 53 kg; Height: 155 cm.

Biospecimens (3 samples)
- Sample MMRF_1931_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1931_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
- Sample MMRF_1931_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 520 days (1.4 years).
